Somatic mutation profile of tumor specimen TARGET-10-PAREGE-09A (aliquot TARGET-10-PAREGE-09A-01D) from TARGET case TARGET-10-PAREGE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,459 days).
Specimen TARGET-10-PAREGE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 146f0be3-0644-4f01-a91f-82d8b24cf14e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREGE-10A (Blood Derived Normal), aliquot TARGET-10-PAREGE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3c7159c-6f12-4b25-a54e-ed9e65fbb61d

The open-access MAF lists 34 somatic variants for this specimen: 16 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 11, Intron 3, 3'UTR 2, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKFN1 | c.1485G>T p.R495S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV59443442; called by muse, mutect2
- CTAG2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs782810865, COSV99909078; called by muse, mutect2
- EMC2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); catalogued as rs1399101600; called by muse, mutect2
- INTU | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99611500; called by muse, mutect2, varscan2
- MYO1G | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs529667295, COSV51852975; called by muse, mutect2, varscan2
- OTOG | c.7409C>T p.P2470L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs971510546; called by muse, mutect2, varscan2
- PLEKHG5 | c.3080G>A p.R1027Q (on ENST00000400915 / NM_001042663.3; = p.R990Q on NM_020631.6) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs762876171; called by muse, varscan2
- SHROOM2 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs369881284, COSV66605016; called by muse, mutect2, varscan2
- TEX15 | c.5203C>T p.R1735C (on ENST00000256246; = p.R2118C on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1324071477; called by muse, mutect2
- TP53 | c.841_842insCCCAGAA p.D281Afs*27 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | catalogued as COSV53389166; called by mutect2, pindel*
- VAC14 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs781619169; called by muse, mutect2, varscan2
- DOT1L | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGB2 | c.358_375delinsTCTTGGGGG p.L120_T125delinsSWG | In Frame Del (DEL) | VAF 36/139 reads (26%) | called by pindel, varscan2*
- RGMB | c.245G>T p.C82F (on ENST00000513185 / NM_001366508.1; = p.C123F on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBN1 | c.466A>G p.K156E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- WDR46 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ARHGAP27 | c.750G>A p.P250= | Silent (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- CFAP46 | c.3324G>A p.A1108= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs757690129; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1386C>T p.H462= | Silent (SNP) | VAF 54/170 reads (32%) | catalogued as rs561419730; called by muse, mutect2, varscan2
- MAEL | c.162C>T p.Y54= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs779808013, COSV100901558, COSV63305472; called by muse, mutect2, varscan2
- OR9G1 | c.198G>A p.S66= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs778129132, COSV56448890; called by muse, mutect2
- PADI3 | c.477G>A p.P159= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs569073155, COSV64934794; called by muse, mutect2, varscan2
- PALM3 | c.1510C>T p.L504= (on ENST00000340790; = p.L519= on NM_001145028.2) | Silent (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- RASSF5 | c.615G>A p.P205= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs376852062; called by muse, mutect2, varscan2
- SEC23IP | c.432T>G p.A144= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- TSPAN4 | c.714G>A p.A238= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs145137446; called by muse, mutect2, varscan2
- UBE2O | c.3858G>A p.P1286= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs200208578, COSV100039489; called by muse, mutect2, varscan2
- AC078899.4 | n.840G>A | RNA (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- CCN1 | c.*91G>C | 3'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs1457721990; called by muse, mutect2
- ENTPD5 | c.297+27G>A | Intron (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- KIAA1522 | c.-63C>T | 5'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- PHLPP2 | c.418+3979C>T | Intron (SNP) | VAF 21/90 reads (23%) | catalogued as rs566208736; called by muse, mutect2
- SGSM1 | c.*16G>A | 3'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as rs1287318507; called by muse, mutect2
- SNTN | c.286-231A>G | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as rs1488929649; called by muse, mutect2, varscan2
